Gene-level copy-number profile of tumor specimen TCGA-14-0789-01A from TCGA case TCGA-14-0789, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.9 years (20,050 days).
Specimen TCGA-14-0789-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.1dc3044b-2d7c-4a31-be19-afdf96f4d0b1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-14-0789-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ae79711f-b289-4dad-91ed-32d9a10a57be

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 2: 4,981; copy number 4: 48,831; copy number 6: 5,990; copy number 12: 2; copy number 13: 9; copy number 47: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-14-0789-01A-01D-0384-01): tumor purity 0.56, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:22,117,665–22,214,672, 2 genes: AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:18,630,846–18,859,682, 2 genes, copy number 12 (within-gene range 4–12): PAX7, TAS1R2.
- chr7:54,933,699–55,255,635, 5 genes, copy number 47 (within-gene range 6–47): AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1.
- chr21:32,402,511–32,625,096, 9 genes, copy number 13 (within-gene range 4–13): CFAP298-TCP10L, EVA1C, EXOSC3P1, TCP10L, AP000272.1, RNA5SP490, CFAP298, OR7E23P, AP000275.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
